Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4I5, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4I5-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #:

1

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

VERIFIED BY:

Source of Specimen: History of thyroid cancer. Clinical Diagnosis: Thyroid cancer. Operative Procedure: Total thyroidectomy and central neck dissection.

PROCEDURE: SPGD

1. "Total thyroid"

Received fresh in a small container is an 11.9 gram thyroid, right lobe 4.5 x 2.5 x 1.2 cm, isthmus 1.2 x 1.0 x 0.3 cm and left lobe 3.5 x 2.6 x 0.4 cm. The right lower lobe is remarkable for a 1.2 x 1.7 x 0.8 cm pale tan nodule with possible cystic degeneration. Remainder of right lobe demonstrates unremarkable parenchyma with multiple brown nodules (up to 0.7 cm) filled with dark brown fluid. Left lobe and isthmus demonstrates unremarkable parenchyma.

1A-C. Right thyroid nodule, entirely submitted.

1D. Right mid and upper lobe.

1E. Isthmus.

1F. Left lower lobe.

1G. Left mid and upper lobe.

2. "Central neck dissection, right central neck lymph nodes"

Received in a small container of formalin is a 0.7 x 0.4 cm fibroadipose tissue fragment.

2A. Entirely submitted.

ICD-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C93.9

PROCEDURE: SPMI

PAPILLARY THYROID CARCINOMA

Size of largest primary tumor: 1.7 cm

Location(s): Right lobe

Capsular Invasion: Yes

Vascular Invasion: No

Margins: Negative

Extrathyroidal extension: No

Lymph node metastases: No

Extranodal extension: N/A

JW
10/1/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

NAME: [REDACTED]

BIRTHDATE:

PAGE #: 2

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

SIDE	LEVEL	#POSITIVE NODES	#TOTAL NODES
Central		0	1

PROCEDURE: SPDX

1. Thyroid, resection: Papillary thyroid carcinoma (1.7 cm), arising in the right lobe and confined to the thyroid. Capsular invasion present. Negative for vascular invasion. Surgical margins free. One perithyroidal lymph node negative for malignancy (0/1). Please see TEMPLATE for details.

2. Soft tissue of central neck, dissection: One lymph node negative for malignancy (0/1).

1, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file 9e592313-39d3-4389-abe7-29dd9a321c24 (TCGA-KS-A4I5.801C7861-F776-44D4-A594-4303B4F8A3F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).